Somatic mutation profile of tumor specimen TCGA-XM-A8RI-01A (aliquot TCGA-XM-A8RI-01A-12D-A423-09) from TCGA case TCGA-XM-A8RI, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type B2, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 77.3 years (28,246 days).
Specimen TCGA-XM-A8RI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce8ff38f-bcb0-455b-96cb-532d5a169c3e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XM-A8RI-10A (Blood Derived Normal), aliquot TCGA-XM-A8RI-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df7f10f1-ba27-43d1-8745-3e5d8e434972

The open-access MAF lists 16 somatic variants for this specimen: 9 protein-altering or splice-affecting, 7 silent.
By variant classification: Silent 7, Missense Mutation 6, Nonsense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.2428C>T p.R810* | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | catalogued as rs1555918056, CM095797, COSV60703357; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FANK1 | c.10C>T p.Q4* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | hotspot (GDC flag); catalogued as rs202109621, COSV64160606; called by muse, varscan2
- LRRC41 | c.1978C>A p.Q660K | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.373); catalogued as COSV58440662; called by muse, mutect2
- NLGN4X | c.1041C>A p.D347E | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV52006388; called by mutect2, varscan2
- SIGLEC8 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.887); catalogued as COSV58475781; called by muse, mutect2
- ZBED9 | c.1621G>A p.V541I | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.001); catalogued as rs1444146624; called by muse, mutect2
- COL25A1 | c.1436G>C p.G479A | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FOXC1 | c.201C>A p.Y67* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | called by mutect2, varscan2
- PLEKHG4B | c.476G>A p.G159E (on ENST00000283426; = p.G515E on NM_052909.5) | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CHEK1 | c.1173A>G p.Q391= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV99629822; called by muse, mutect2, varscan2
- CYB5R1 | c.837G>A p.G279= | Silent (SNP) | VAF 6/46 reads (13%) | called by muse, varscan2
- CYP3A43 | c.1158G>A p.V386= | Silent (SNP) | VAF 8/89 reads (9%) | called by muse, mutect2, varscan2
- SLU7 | c.1134C>A p.G378= | Silent (SNP) | VAF 11/81 reads (14%) | called by muse, mutect2, varscan2
- SNX19 | c.1542C>T p.A514= | Silent (SNP) | VAF 7/23 reads (30%) | called by muse, mutect2, varscan2
- SOX1 | c.195G>A p.Q65= | Silent (SNP) | VAF 7/64 reads (11%) | called by muse, mutect2, varscan2
- TSEN34 | c.840T>C p.L280= | Silent (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
